Somatic mutation profile of tumor specimen TCGA-AG-3580-01A (aliquot TCGA-AG-3580-01A-01D-1989-10) from TCGA case TCGA-AG-3580, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 67.8 years (24,775 days).
Specimen TCGA-AG-3580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d179aae1-9187-4d15-b4ba-ac24f803af85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3580-10A (Blood Derived Normal), aliquot TCGA-AG-3580-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3734ffc3-6a25-49be-b620-b7aa9c9a6575

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1347596088, COSV101186993; called by muse, mutect2, varscan2
- ANKRD53 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721443; called by muse, mutect2, varscan2
- ARHGAP39 | c.2900A>G p.K967R (on ENST00000276826 / NM_001308208.2; = p.K998R on NM_025251.2) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99431634; called by muse, mutect2
- COL12A1 | c.8413C>A p.Q2805K | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV100486174; called by muse, mutect2, varscan2
- GP6 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.236); catalogued as rs764355964, COSV100117598, COSV59976444; called by muse, mutect2, varscan2
- MSC | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV100335776; called by muse, mutect2, varscan2
- MYSM1 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101284053; called by muse, mutect2, varscan2
- NUBP1 | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99296834; called by muse, mutect2, varscan2
- SEPTIN8 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 99/295 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV99736365; called by muse, mutect2, varscan2
- SPEF2 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV100289153; called by muse, mutect2
- WFIKKN1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs746390568, COSV99937815; called by muse, varscan2
- DEFB110 | c.56-33_56-1del p.X19_splice | Splice Site (DEL) | VAF 46/170 reads (27%) | called by mutect2, pindel
- CACNG8 | c.585G>A p.E195= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99555052; called by muse, mutect2, varscan2
- GPR78 | c.231C>T p.G77= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs772431301, COSV66762943; called by muse, mutect2
- MEGF11 | c.2097C>T p.P699= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs752887236, COSV56547443; called by muse, mutect2, varscan2
- PCDHA9 | c.2004G>A p.S668= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV65324280; called by muse, mutect2, varscan2
- PRDX2 | c.54A>G p.T18= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV100040244; called by muse, mutect2, varscan2
- RBM15B | c.1440A>G p.G480= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100082206; called by muse, mutect2, varscan2
